Gene-level copy-number profile of tumor specimen TCGA-66-2782-01A from TCGA case TCGA-66-2782, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.8 years (26,237 days).
Specimen TCGA-66-2782-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8b310508-be7a-4714-93d2-6b427db221b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2782-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8473ef42-e762-4155-832d-ff3bcc5a4eeb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 243; copy number 1: 1,302; copy number 2: 18,259; copy number 3: 18,779; copy number 4: 18,094; copy number 5: 977; copy number 6: 1,202; copy number 8: 934; copy number 19: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2782-01A-01D-0844-01): tumor purity 0.52, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 241 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:1,246,789–1,381,394, 5 genes: AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4.
- chr8:2,033,508–2,838,823, 11 genes: AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1.
- chr8:5,072,645–5,142,707, 4 genes: AC019176.1, AC019176.2, SNORA70, RN7SL318P.
- chr8:6,403,551–8,386,439, 122 genes (within-gene range 0–2) (broad region; genes not listed).
- chr8:10,433,672–12,665,588, 99 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 952 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,163,335–38,560,939, 18 genes, copy number 19: LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.
- chr8:85,826,865–145,066,685, 934 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
